Somatic mutation profile of tumor specimen ALCH-B2TV-TTP1-A (aliquot ALCH-B2TV-TTP1-A-1-0-D-A78Q-36) from ALCHEMIST case ALCH-B2TV, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 76.4 years (27,905 days).
Specimen ALCH-B2TV-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 247ce5f3-3b19-4623-9b99-c2d6a7553b63.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2TV-NB1-A (Blood Derived Normal), aliquot ALCH-B2TV-NB1-A-1-0-D-A78Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c2b2ebd0-7dec-40da-af3b-e16b6e74d0f8

The open-access MAF lists 266 somatic variants for this specimen: 180 protein-altering or splice-affecting, 50 silent, 36 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 157, Silent 50, Intron 20, Nonsense Mutation 10, RNA 7, Frame Shift Del 7, 5'UTR 6, Splice Site 4, 5'Flank 3, Splice Region 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 33/248 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- SF3B1 | c.1997A>C p.K666T | Missense Mutation (SNP) | VAF 24/246 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs374250186, COSV59205833, COSV59206062, COSV59207657; ClinVar: likely pathogenic; called by muse, mutect2
- SMAD4 | c.1067C>G p.P356R | Missense Mutation (SNP) | VAF 16/144 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61685209, COSV61685537, COSV61689602; called by muse, mutect2
- ABCA8 | c.298G>T p.A100S | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as rs1317722479; called by muse, varscan2
- ACSS3 | c.506A>C p.D169A | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54088891; called by muse, mutect2
- ADAMTS12 | c.4648del p.Q1550Rfs*3 | Frame Shift Del (DEL) | VAF 36/184 reads (20%) | catalogued as COSV100711393; called by mutect2, pindel, varscan2
- ANK2 | c.3991G>A p.V1331I | Missense Mutation (SNP) | VAF 33/377 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1163149906; called by muse, mutect2
- ANKDD1B | c.588C>A p.N196K | Missense Mutation (SNP) | VAF 15/157 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); catalogued as rs1429110125; called by muse, mutect2, varscan2
- ASB18 | c.1246del p.A416Pfs*? | Frame Shift Del (DEL) | VAF 8/68 reads (12%) | catalogued as COSV100430841, COSV58233222; called by mutect2, pindel
- BRINP1 | c.1120C>A p.P374T | Missense Mutation (SNP) | VAF 22/250 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV56300186; called by muse, mutect2
- C2orf78 | c.395C>G p.T132R | Missense Mutation (SNP) | VAF 11/166 reads (7%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.447); catalogued as rs369481277; called by muse, mutect2
- CACNA1H | c.3317G>T p.G1106V | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.348); catalogued as COSV62000090; called by muse, mutect2, varscan2
- CARD6 | c.1735T>C p.C579R | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); catalogued as rs1372295239; called by muse, mutect2, varscan2
- CCER1 | c.53G>T p.G18V | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV99076283; called by muse, mutect2
- CDH18 | c.2284C>A p.Q762K | Missense Mutation (SNP) | VAF 16/222 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as COSV99931832, COSV99934322; called by muse, mutect2
- CTR9 | c.145-1G>C p.X49_splice | Splice Site (SNP) | VAF 14/99 reads (14%) | catalogued as COSV63730073; called by muse, mutect2, varscan2
- DMBT1 | c.7216G>T p.D2406Y (on ENST00000338354 / NM_001377530.1; = p.D1649Y on NM_004406.3) | Missense Mutation (SNP) | VAF 36/351 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.542); catalogued as COSV57544201; called by muse, mutect2, varscan2
- DMRT2 | c.1325C>A p.T442K | Missense Mutation (SNP) | VAF 22/208 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs749570805, COSV99426347; called by muse, mutect2, varscan2
- DST | c.15637A>G p.T5213A (on ENST00000361203 / NM_001374722.1; = p.T2801A on NM_015548.5) | Missense Mutation (SNP) | VAF 34/380 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99760327; called by muse, mutect2
- EDA2R | c.856C>A p.L286M | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs1256843965; called by muse, mutect2
- EPHA3 | c.1202C>A p.A401E | Missense Mutation (SNP) | VAF 24/260 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60710314; called by muse, mutect2
- FITM2 | c.40A>T p.T14S | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.05); catalogued as rs1449584842; called by muse, mutect2, varscan2
- GAB4 | c.97G>T p.G33* | Nonsense Mutation (SNP) | VAF 12/120 reads (10%) | catalogued as COSV101271868; called by muse, mutect2
- GDA | c.176G>T p.C59F | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1307661828, COSV99430022; called by muse, mutect2
- INPP4B | c.445A>C p.S149R | Missense Mutation (SNP) | VAF 15/230 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.387); catalogued as COSV99523277; called by muse, mutect2
- IST1 | c.820A>G p.M274V (on ENST00000535424 / NM_001270976.1; = p.M261V on NM_014761.4) | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs189085705; called by muse, mutect2, varscan2
- KCNK2 | c.202G>A p.V68M (on ENST00000444842 / NM_001017425.3; = p.V53M on NM_014217.4) | Missense Mutation (SNP) | VAF 27/304 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.56); catalogued as rs774410659; called by muse, mutect2
- KCNV2 | c.1217A>T p.Q406L | Missense Mutation (SNP) | VAF 24/201 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs768545361; called by muse, mutect2, varscan2
- LRP4 | c.5519A>G p.H1840R | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.888); catalogued as rs148761432; called by muse, mutect2, varscan2
- LRRC25 | c.325G>T p.D109Y | Missense Mutation (SNP) | VAF 19/160 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as COSV59114757; called by muse, mutect2, varscan2
- MED15 | c.1942G>A p.A648T (on ENST00000263205 / NM_001003891.3; = p.A608T on NM_015889.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/177 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs148867695; called by muse, mutect2, varscan2
- MMP12 | c.162A>C p.K54N | Missense Mutation (SNP) | VAF 39/240 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.864); catalogued as rs1555009641; called by muse, mutect2, varscan2
- MYO18B | c.3118G>T p.D1040Y | Missense Mutation (SNP) | VAF 31/278 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59152639; called by muse, mutect2, varscan2
- NLRC3 | c.1070C>G p.P357R | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100073499, COSV57087125; called by mutect2, varscan2
- OR11L1 | c.356C>A p.A119D | Missense Mutation (SNP) | VAF 16/234 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs774202091; called by muse, mutect2
- OR2M2 | c.509G>T p.G170V | Missense Mutation (SNP) | VAF 18/322 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV62897726, COSV62897788; called by muse, mutect2
- PAPPA2 | c.1426C>A p.P476T | Missense Mutation (SNP) | VAF 32/506 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as rs1332471953; called by muse, mutect2
- PCDHB6 | c.836C>A p.A279D | Missense Mutation (SNP) | VAF 18/323 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.903); catalogued as rs1043178803; called by muse, mutect2
- PDGFRA | c.464C>G p.P155R | Missense Mutation (SNP) | VAF 23/250 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57267262; called by muse, mutect2
- PLA2G6 | c.2256G>A p.M752I | Missense Mutation (SNP) | VAF 20/234 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as rs1331383014; called by muse, mutect2
- PLPPR4 | c.1778C>A p.P593H | Missense Mutation (SNP) | VAF 14/171 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV100926819; called by muse, mutect2
- PNPLA5 | c.1112C>A p.A371E | Missense Mutation (SNP) | VAF 17/192 reads (9%) | SIFT tolerated (0.5); PolyPhen benign (0.026); catalogued as COSV53376438, COSV53376780; called by muse, mutect2
- PPP1R16B | c.1388C>T p.A463V | Missense Mutation (SNP) | VAF 33/378 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.034); catalogued as rs780085035; called by muse, mutect2
- PPP1R18 | c.227C>T p.A76V | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.066); catalogued as rs1003665689; called by muse, mutect2
- PSG8 | c.600G>T p.R200S | Missense Mutation (SNP) | VAF 26/418 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs1322551149; called by muse, mutect2
- ROBO1 | c.3546G>A p.W1182* | Nonsense Mutation (SNP) | VAF 26/390 reads (7%) | catalogued as rs1479121782; called by muse, mutect2
- RRP8 | c.784C>T p.P262S | Missense Mutation (SNP) | VAF 22/286 reads (8%) | SIFT tolerated (0.46); PolyPhen benign (0.029); catalogued as rs539994234; called by muse, mutect2
- SELENOF | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.157); catalogued as rs761918119, COSV59354714; called by muse, mutect2, varscan2
- SHQ1 | c.1357G>T p.E453* | Nonsense Mutation (SNP) | VAF 12/143 reads (8%) | catalogued as COSV57767437; called by muse, mutect2
- SIGLEC1 | c.3625G>A p.G1209S | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.924); catalogued as rs141006719; called by muse, mutect2, varscan2
- SLC35F4 | c.50A>C p.Q17P | Missense Mutation (SNP) | VAF 24/268 reads (9%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs1261889185; called by muse, mutect2
- SLC4A3 | c.1070G>T p.R357L | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.527); catalogued as COSV56091906; called by muse, mutect2
- SLC6A7 | c.79G>A p.V27I | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs201896345; called by muse, mutect2
- STON2 | c.1974C>G p.I658M (on ENST00000649389 / NM_001366849.2; = p.I601M on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0.419); catalogued as COSV50844847; called by muse, mutect2
- SUMF1 | c.13G>C p.A5P | Missense Mutation (SNP) | VAF 23/244 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.308); catalogued as rs1225993664, COSV55991577; called by muse, mutect2
- TGIF2LY | c.320G>T p.R107L | Missense Mutation (SNP) | VAF 61/317 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV58291604; called by muse, mutect2, varscan2
- THSD7A | c.1360C>A p.L454I | Missense Mutation (SNP) | VAF 24/294 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.465); catalogued as COSV70261739; called by muse, mutect2
- TMEM200A | c.1171C>A p.L391I | Missense Mutation (SNP) | VAF 13/245 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV51652685; called by muse, mutect2
- TNFRSF17 | c.115C>T p.R39C | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.825); catalogued as rs550606391; called by muse, mutect2, varscan2
- TRAF7 | c.1566G>T p.W522C | Missense Mutation (SNP) | VAF 31/167 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV58216318; called by muse, mutect2, varscan2
- TTC39B | c.841del p.L281Cfs*30 | Frame Shift Del (DEL) | VAF 17/139 reads (12%) | catalogued as COSV99895833; called by mutect2, pindel, varscan2
- TUBB8 | c.157G>T p.E53* | Nonsense Mutation (SNP) | VAF 18/200 reads (9%) | catalogued as COSV59116323; called by muse, mutect2
- A2M | c.3984G>C p.L1328F | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.327); called by muse, mutect2
- ABCB5 | c.980C>A p.A327D | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- ADAMTS14 | c.3440G>T p.R1147L | Missense Mutation (SNP) | VAF 11/119 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2
- ADAMTS5 | c.2345G>C p.G782A | Missense Mutation (SNP) | VAF 12/193 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2
- AGFG2 | c.1020G>T p.Q340H | Missense Mutation (SNP) | VAF 34/177 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ANKRD17 | c.4750A>T p.I1584L | Missense Mutation (SNP) | VAF 28/360 reads (8%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2
- ARHGEF10 | c.2698G>T p.A900S (on ENST00000398564; = p.A875S on NM_014629.4) | Missense Mutation (SNP) | VAF 64/404 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.416); called by muse, mutect2, varscan2
- ARNT2 | c.1369T>C p.S457P | Missense Mutation (SNP) | VAF 20/205 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.16); called by muse, mutect2
- ATP6V1F | c.156C>T p.F52= | Splice Region (SNP) | VAF 12/130 reads (9%) | called by muse, mutect2
- BAHCC1 | c.6022G>T p.D2008Y | Missense Mutation (SNP) | VAF 17/164 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- C10orf90 | c.1465C>A p.P489T | Missense Mutation (SNP) | VAF 20/167 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CARD11 | c.3112G>T p.A1038S | Missense Mutation (SNP) | VAF 14/186 reads (8%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2
- CBFA2T2 | c.1549A>T p.T517S | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by mutect2, varscan2
- CC2D1B | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 29/336 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.081); called by muse, mutect2
- CCDC74A | c.1096C>T p.Q366* | Nonsense Mutation (SNP) | VAF 16/180 reads (9%) | called by muse, mutect2, varscan2
- CCIN | c.1657C>A p.L553M | Missense Mutation (SNP) | VAF 28/280 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2
- CCNP | c.569G>T p.R190L | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); called by muse, mutect2
- CENPE | c.1741G>C p.V581L | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CEP120 | c.886A>T p.T296S | Missense Mutation (SNP) | VAF 47/267 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CHD6 | c.7463C>T p.P2488L | Missense Mutation (SNP) | VAF 12/129 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- CLTCL1 | c.839G>T p.G280V | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2
- CSMD3 | c.3439G>C p.A1147P (on ENST00000297405 / NM_001363185.1; = p.A1043P on NM_052900.3) | Missense Mutation (SNP) | VAF 28/454 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DAZL | c.244T>A p.Y82N | Missense Mutation (SNP) | VAF 11/194 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DCAF12L2 | c.1230G>C p.W410C | Missense Mutation (SNP) | VAF 43/116 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DCBLD2 | c.840A>T p.L280F | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DMD | c.4306G>A p.A1436T | Missense Mutation (SNP) | VAF 32/196 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DOP1A | c.2941C>A p.L981M | Missense Mutation (SNP) | VAF 27/271 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DPF2 | c.434_435del p.E145Vfs*17 | Frame Shift Del (DEL) | VAF 19/119 reads (16%) | called by mutect2, pindel, varscan2
- DYNC1H1 | c.12924G>T p.W4308C | Missense Mutation (SNP) | VAF 42/499 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EPHX2 | c.232G>C p.A78P | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ERICH5 | c.578A>T p.N193I | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.311); called by muse, mutect2
- ERVH48-1 | c.35C>G p.S12C | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.394); called by muse, mutect2, varscan2
- F2RL2 | c.586G>T p.V196F | Missense Mutation (SNP) | VAF 20/192 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- FAM71F1 | c.953G>T p.G318V | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2
- FNBP1 | c.1074G>T p.Q358H | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FOCAD | c.1855A>T p.K619* | Nonsense Mutation (SNP) | VAF 12/174 reads (7%) | called by muse, mutect2
- FSIP2 | c.16548T>A p.N5516K | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- GABRB2 | c.227A>T p.E76V | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- GAP43 | c.586C>G p.P196A | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.334); called by muse, mutect2
- GGT7 | c.1426G>T p.V476L | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.726); called by muse, mutect2
- GIMAP8 | c.1459C>A p.Q487K | Missense Mutation (SNP) | VAF 29/193 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- GSG1L2 | c.458G>A p.G153E | Missense Mutation (SNP) | VAF 24/222 reads (11%) | SIFT tolerated (0.74); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- GSX2 | c.137C>A p.S46Y | Missense Mutation (SNP) | VAF 43/421 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- GZMM | c.548A>T p.N183I | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.244); called by muse, mutect2
- HIVEP1 | c.4878G>T p.Q1626H | Missense Mutation (SNP) | VAF 24/216 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.03); called by muse, mutect2
- HTR1A | c.85T>A p.S29T | Missense Mutation (SNP) | VAF 78/477 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- IL1RAPL1 | c.2042T>A p.I681N | Missense Mutation (SNP) | VAF 34/202 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.095); called by muse, varscan2
- ITGB8 | c.2167A>G p.R723G | Missense Mutation (SNP) | VAF 26/236 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- KCNU1 | c.1856G>T p.C619F | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- KCNU1 | c.1857T>A p.C619* | Nonsense Mutation (SNP) | VAF 10/76 reads (13%) | called by muse, varscan2
- KCNU1 | c.1858G>T p.G620C | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.011); called by muse, varscan2
- KCNV2 | c.1218G>T p.Q406H | Missense Mutation (SNP) | VAF 24/202 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- KIAA1755 | c.3223G>T p.A1075S | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.196); called by muse, mutect2
- LCLAT1 | c.977A>G p.Y326C | Missense Mutation (SNP) | VAF 31/279 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAGI3 | c.1114G>T p.E372* | Nonsense Mutation (SNP) | VAF 19/204 reads (9%) | called by muse, mutect2
- MED9 | c.241C>G p.P81A | Missense Mutation (SNP) | VAF 22/212 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.266); called by muse, varscan2
- MPDZ | c.2090G>C p.G697A | Missense Mutation (SNP) | VAF 22/241 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2
- MUC16 | c.10146G>T p.L3382F | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MYT1 | c.2696T>A p.V899E | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.439); called by muse, mutect2
- NDUFAF1 | c.523G>C p.G175R | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NEGR1 | c.387G>T p.M129I | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.062); called by muse, mutect2
- NEU2 | c.74T>G p.L25R | Missense Mutation (SNP) | VAF 20/323 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- NLRC3 | c.490C>T p.H164Y | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.13); called by muse, mutect2
- NRXN3 | c.3123G>T p.Q1041H (on ENST00000335750 / NM_001330195.2; = p.Q668H on NM_004796.6) | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2
- NUTM2A | c.606C>A p.N202K | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0.114); called by mutect2, varscan2
- OR10A4 | c.206T>A p.F69Y | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.597); called by muse, mutect2
- OR2AG2 | c.164T>A p.L55H | Missense Mutation (SNP) | VAF 59/299 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR2F2 | c.168del p.H56Qfs*22 | Frame Shift Del (DEL) | VAF 26/179 reads (15%) | called by mutect2, varscan2
- OR2T27 | c.47G>A p.G16D | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, varscan2
- OTOG | c.4519C>T p.H1507Y | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- PDCD11 | c.3994G>T p.G1332W | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.379); called by muse, mutect2
- PDE6C | c.1737+1G>A p.X579_splice | Splice Site (SNP) | VAF 30/364 reads (8%) | called by muse, mutect2
- PEAK1 | c.3197G>T p.G1066V | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2
- PEX13 | c.157C>A p.P53T | Missense Mutation (SNP) | VAF 21/162 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PGM3 | c.913A>C p.I305L | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.839); called by muse, mutect2
- PHLPP2 | c.2299del p.I767Lfs*74 | Frame Shift Del (DEL) | VAF 24/248 reads (10%) | called by mutect2, pindel
- PLB1 | c.2438C>T p.A813V | Missense Mutation (SNP) | VAF 15/212 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PLCB4 | c.515C>T p.T172I | Missense Mutation (SNP) | VAF 7/112 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); called by muse, mutect2
- PLCE1 | c.4113C>T p.A1371= | Splice Region (SNP) | VAF 20/450 reads (4%) | called by muse, mutect2
- PLEKHG2 | c.1876A>G p.M626V | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); called by muse, mutect2
- PXDN | c.2471T>A p.F824Y | Missense Mutation (SNP) | VAF 38/369 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RASA3 | c.433del p.H145Tfs*16 | Frame Shift Del (DEL) | VAF 22/204 reads (11%) | called by mutect2, pindel
- RBMX2 | c.794G>T p.R265M | Missense Mutation (SNP) | VAF 72/221 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- RORC | c.442A>T p.T148S | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.99); PolyPhen benign (0); called by muse, mutect2, varscan2
- RPS11 | c.302G>T p.R101L | Missense Mutation (SNP) | VAF 39/381 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.39); called by muse, mutect2, varscan2
- RYR3 | c.4576C>A p.L1526M | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.233); called by muse, mutect2, varscan2
- SALL1 | c.2716G>A p.G906S | Missense Mutation (SNP) | VAF 16/206 reads (8%) | SIFT tolerated (0.87); PolyPhen possibly damaging (0.52); called by muse, mutect2
- SCN1A | c.1859G>T p.S620I | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.115); called by muse, mutect2
- SEL1L2 | c.649T>A p.S217T | Missense Mutation (SNP) | VAF 10/187 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- SLC26A4 | c.1264-2A>G p.X422_splice | Splice Site (SNP) | VAF 46/558 reads (8%) | called by muse, mutect2
- SLC8A3 | c.1966G>T p.G656* (on ENST00000381269 / NM_183002.3; = p.G654* on NM_033262.4) | Nonsense Mutation (SNP) | VAF 6/90 reads (7%) | called by muse, mutect2
- SNTG1 | c.899A>G p.D300G | Missense Mutation (SNP) | VAF 20/160 reads (13%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.98); called by muse, varscan2
- SPTA1 | c.6209T>G p.V2070G | Missense Mutation (SNP) | VAF 26/176 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SUGP1 | c.1801G>C p.G601R | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2
- SVEP1 | c.6977C>A p.P2326Q | Missense Mutation (SNP) | VAF 22/216 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SYNE2 | c.2986A>G p.M996V | Missense Mutation (SNP) | VAF 37/355 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2
- TAAR5 | c.716G>T p.S239I | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- TAF1L | c.5224G>T p.G1742C | Missense Mutation (SNP) | VAF 42/349 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- TBX5 | c.1507C>A p.H503N | Missense Mutation (SNP) | VAF 23/273 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- TIMD4 | c.26G>T p.W9L | Missense Mutation (SNP) | VAF 30/213 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TNR | c.392C>G p.A131G | Missense Mutation (SNP) | VAF 106/482 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- TNXB | c.5287C>A p.Q1763K (on ENST00000647633; = p.Q1516K on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/380 reads (5%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.718); called by muse, mutect2
- TRABD2A | c.1334G>T p.S445I (on ENST00000409520 / NM_001277053.2; = p.S396I on NM_001080824.3) | Missense Mutation (SNP) | VAF 11/136 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); called by muse, mutect2
- TRPM7 | c.3344G>T p.R1115L | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- TSPEAR | c.569C>A p.T190N | Missense Mutation (SNP) | VAF 12/219 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0.05); called by muse, mutect2
- UMOD | c.240C>A p.N80K | Missense Mutation (SNP) | VAF 120/575 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- UNC13C | c.5061-2A>T p.X1687_splice | Splice Site (SNP) | VAF 11/93 reads (12%) | called by muse, mutect2, varscan2
- UNC79 | c.152C>A p.S51Y | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- WDFY3 | c.4260G>C p.M1420I | Missense Mutation (SNP) | VAF 16/196 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- YTHDC2 | c.647G>C p.G216A | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZBTB6 | c.573G>C p.E191D | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ZG16B | c.116T>A p.L39Q | Missense Mutation (SNP) | VAF 50/190 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ZMAT2 | c.141G>T p.E47D | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF202 | c.730G>T p.V244L | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF256 | c.272C>A p.P91H | Missense Mutation (SNP) | VAF 28/297 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.332); called by muse, mutect2
- ZNF527 | c.1648G>T p.G550* | Nonsense Mutation (SNP) | VAF 20/122 reads (16%) | called by muse, mutect2, varscan2
- ZNF585B | c.1664G>T p.C555F | Missense Mutation (SNP) | VAF 10/131 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZNF646 | c.2445G>T p.W815C | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); called by muse, mutect2
- ABCA1 | c.2151G>T p.V717= | Silent (SNP) | VAF 40/346 reads (12%) | called by muse, mutect2, varscan2
- ABCA12 | c.2223C>A p.A741= (on ENST00000272895 / NM_173076.3; = p.A423= on NM_015657.3) | Silent (SNP) | VAF 36/379 reads (9%) | called by muse, mutect2
- ADD2 | c.357C>T p.H119= | Silent (SNP) | VAF 38/321 reads (12%) | called by muse, mutect2, varscan2
- ATP6V1C1 | c.879A>T p.A293= | Silent (SNP) | VAF 22/131 reads (17%) | called by muse, mutect2, varscan2
- ATXN3L | c.57G>T p.L19= | Silent (SNP) | VAF 17/72 reads (24%) | called by muse, mutect2, varscan2
- AXDND1 | c.2688A>T p.L896= | Silent (SNP) | VAF 20/128 reads (16%) | called by muse, mutect2, varscan2
- BMP7 | c.852G>C p.T284= | Silent (SNP) | VAF 45/383 reads (12%) | called by muse, mutect2, varscan2
- C6orf118 | c.384G>T p.L128= | Silent (SNP) | VAF 6/116 reads (5%) | called by muse, mutect2
- CADM3 | c.678C>G p.R226= (on ENST00000368125 / NM_001127173.3; = p.R260= on NM_021189.5) | Silent (SNP) | VAF 26/83 reads (31%) | called by muse, mutect2, varscan2
- CAPN13 | c.1905G>T p.L635= | Silent (SNP) | VAF 27/253 reads (11%) | catalogued as COSV54430159, COSV54432250; called by muse, mutect2
- CARD11 | c.951G>A p.Q317= | Silent (SNP) | VAF 34/201 reads (17%) | catalogued as rs563068593; called by muse, mutect2, varscan2
- CCT8L2 | c.444C>A p.P148= | Silent (SNP) | VAF 8/105 reads (8%) | catalogued as COSV100743038; called by muse, mutect2
- CELSR1 | c.1140C>T p.R380= | Silent (SNP) | VAF 7/98 reads (7%) | called by muse, mutect2
- CNTNAP2 | c.439C>A p.R147= | Silent (SNP) | VAF 37/357 reads (10%) | catalogued as COSV62248397; called by muse, mutect2, varscan2
- COL19A1 | c.3171G>T p.G1057= | Silent (SNP) | VAF 12/158 reads (8%) | called by muse, mutect2
- CST9 | c.54C>A p.L18= | Silent (SNP) | VAF 19/195 reads (10%) | called by muse, mutect2, varscan2
- DCDC1 | c.1362A>T p.I454= | Silent (SNP) | VAF 12/168 reads (7%) | called by muse, mutect2
- DCDC2C | c.999C>T p.N333= | Silent (SNP) | VAF 10/229 reads (4%) | called by muse, mutect2
- FLG | c.2769T>A p.S923= | Silent (SNP) | VAF 58/579 reads (10%) | called by muse, varscan2
- FMNL3 | c.1044C>T p.T348= | Silent (SNP) | VAF 13/113 reads (12%) | catalogued as COSV99525873; called by muse, mutect2, varscan2
- GDF10 | c.858C>A p.P286= | Silent (SNP) | VAF 6/72 reads (8%) | called by muse, mutect2
- GPIHBP1 | c.264C>A p.T88= | Silent (SNP) | VAF 53/278 reads (19%) | catalogued as rs1398231770; called by muse, mutect2, varscan2
- HOXA3 | c.684G>C p.L228= | Silent (SNP) | VAF 33/246 reads (13%) | catalogued as rs201254304; called by muse, mutect2, varscan2
- IGFN1 | c.666C>A p.I222= | Silent (SNP) | VAF 12/215 reads (6%) | called by muse, mutect2
- IL1RAPL1 | c.2043C>T p.I681= | Silent (SNP) | VAF 34/202 reads (17%) | called by muse, varscan2
- IL5RA | c.1245G>A p.L415= | Silent (SNP) | VAF 16/183 reads (9%) | catalogued as rs1400739411; called by muse, mutect2
- IRS1 | c.447G>A p.L149= | Silent (SNP) | VAF 29/270 reads (11%) | called by muse, mutect2, varscan2
- KAT2B | c.1440C>A p.A480= | Silent (SNP) | VAF 23/217 reads (11%) | called by muse, mutect2, varscan2
- LILRA4 | c.24G>T p.L8= | Silent (SNP) | VAF 21/236 reads (9%) | called by muse, mutect2
- LPXN | c.993G>T p.G331= | Silent (SNP) | VAF 18/272 reads (7%) | called by muse, mutect2
- MAMDC2 | c.1083C>A p.T361= | Silent (SNP) | VAF 17/142 reads (12%) | catalogued as rs771986746, COSV101015403; called by muse, mutect2, varscan2
- MBOAT4 | c.690G>A p.A230= | Silent (SNP) | VAF 33/198 reads (17%) | catalogued as rs978057179, COSV57643381; called by muse, mutect2, varscan2
- MCF2L2 | c.2535C>A p.G845= | Silent (SNP) | VAF 16/167 reads (10%) | called by muse, mutect2
- MROH5 | c.3892C>A p.R1298= | Silent (SNP) | VAF 53/275 reads (19%) | called by muse, mutect2, varscan2
- MVD | c.360G>T p.T120= | Silent (SNP) | VAF 13/160 reads (8%) | called by muse, mutect2
- NANOGNB | c.312C>T p.P104= | Silent (SNP) | VAF 22/250 reads (9%) | catalogued as rs774424251; called by muse, mutect2
- OR10Z1 | c.741G>T p.V247= | Silent (SNP) | VAF 60/204 reads (29%) | called by muse, mutect2, varscan2
- OR11L1 | c.357C>G p.A119= | Silent (SNP) | VAF 15/235 reads (6%) | catalogued as COSV63313562; called by muse, mutect2
- OR51L1 | c.588C>A p.T196= | Silent (SNP) | VAF 14/89 reads (16%) | called by muse, mutect2, varscan2
- PCP2 | c.141C>T p.A47= | Silent (SNP) | VAF 18/178 reads (10%) | catalogued as rs757111561; called by muse, mutect2
- PDE8B | c.147C>A p.A49= | Silent (SNP) | VAF 13/155 reads (8%) | called by muse, mutect2
- RBFOX3 | c.325C>A p.R109= | Silent (SNP) | VAF 7/56 reads (13%) | called by muse, mutect2, varscan2
- SHANK2 | c.612C>T p.A204= | Silent (SNP) | VAF 26/115 reads (23%) | catalogued as rs187315247; called by muse, mutect2, varscan2
- SLC45A2 | c.1428C>T p.C476= | Silent (SNP) | VAF 15/420 reads (4%) | catalogued as rs139551409; called by muse, mutect2
- SLC5A4 | c.390A>G p.E130= | Silent (SNP) | VAF 25/203 reads (12%) | called by muse, mutect2, varscan2
- SLFN11 | c.1326T>C p.S442= | Silent (SNP) | VAF 20/382 reads (5%) | called by muse, mutect2
- SPEF2 | c.2448A>C p.V816= | Silent (SNP) | VAF 8/254 reads (3%) | called by muse, mutect2
- UBA1 | c.2253G>T p.P751= | Silent (SNP) | VAF 38/256 reads (15%) | catalogued as COSV100255997; called by muse, mutect2, varscan2
- WNT9B | c.660C>T p.A220= | Silent (SNP) | VAF 7/97 reads (7%) | catalogued as rs367923609, COSV99255116; called by muse, mutect2
- ZFPM2 | c.897C>T p.P299= | Silent (SNP) | VAF 40/226 reads (18%) | called by muse, mutect2, varscan2
- AC079612.1 | n.247C>A | RNA (SNP) | VAF 38/495 reads (8%) | called by muse, mutect2
- CA6 | c.259+2119G>A | Intron (SNP) | VAF 26/304 reads (9%) | called by muse, mutect2
- CEP164 | c.393+3347A>T | Intron (SNP) | VAF 28/154 reads (18%) | called by muse, mutect2, varscan2
- CFAP65 | c.-22C>A | 5'UTR (SNP) | VAF 25/227 reads (11%) | called by muse, mutect2
- CSNK1D | c.1197+25C>T | Intron (SNP) | VAF 8/55 reads (15%) | catalogued as rs768049315; called by muse, mutect2, varscan2
- DST | c.4297-4039C>A | Intron (SNP) | VAF 23/216 reads (11%) | called by muse, mutect2, varscan2
- EPB41L1 | c.1669-2887G>T | Intron (SNP) | VAF 20/234 reads (9%) | called by muse, mutect2
- EPCAM | chr2:47369233 G>T | 5'Flank (SNP) | VAF 8/166 reads (5%) | called by muse, mutect2
- ERCC6 | c.1397+8418A>C | Intron (SNP) | VAF 12/145 reads (8%) | called by muse, mutect2
- EYS | c.1767-6529C>A | Intron (SNP) | VAF 30/540 reads (6%) | called by muse, mutect2
- FLT4 | c.-43G>T | 5'UTR (SNP) | VAF 5/33 reads (15%) | called by muse, mutect2, varscan2
- GABRB3 | c.241-20956G>A | Intron (SNP) | VAF 16/149 reads (11%) | called by muse, mutect2, varscan2
- GADD45A | c.146+49C>G | Intron (SNP) | VAF 9/87 reads (10%) | called by muse, mutect2
- HEXA | c.1421+45G>T | Intron (SNP) | VAF 7/107 reads (7%) | called by muse, mutect2
- IL4R | c.-10G>T | 5'UTR (SNP) | VAF 16/183 reads (9%) | called by muse, mutect2
- IRX4 | c.408-245C>A | Intron (SNP) | VAF 10/142 reads (7%) | called by muse, mutect2
- JPH3 | c.2167-536G>C | Intron (SNP) | VAF 22/264 reads (8%) | called by muse, mutect2
- LY6K | c.218-159G>A | Intron (SNP) | VAF 8/65 reads (12%) | catalogued as COSV99456220; called by muse, mutect2, varscan2
- MASP1 | c.-42G>A | 5'UTR (SNP) | VAF 23/804 reads (3%) | called by muse, mutect2
- MOGAT3 | chr7:101203147 G>C | 5'Flank (SNP) | VAF 56/385 reads (15%) | called by muse, mutect2, varscan2
- MS4A6A | c.339+28C>A | Intron (SNP) | VAF 18/280 reads (6%) | catalogued as rs777443502; called by muse, mutect2
- MUCL3 | c.947-1264G>T | Intron (SNP) | VAF 53/426 reads (12%) | catalogued as COSV58516297; called by muse, mutect2, varscan2
- NDUFAF2 | c.-38dup | 5'UTR (INS) | VAF 48/434 reads (11%) | called by pindel, varscan2
- OR2L1P | n.630G>T | RNA (SNP) | VAF 45/191 reads (24%) | catalogued as rs1488951188; called by muse, mutect2, varscan2
- OR56B3P | n.691G>C | RNA (SNP) | VAF 34/138 reads (25%) | called by muse, mutect2, varscan2
- PDZD7 | c.-66G>C | 5'UTR (SNP) | VAF 18/262 reads (7%) | called by muse, mutect2
- RAF1 | c.862+45C>G | Intron (SNP) | VAF 14/386 reads (4%) | called by muse, mutect2
- SH2D6 | chr2:85434083 C>T | 5'Flank (SNP) | VAF 16/184 reads (9%) | called by muse, mutect2
- SLC22A11 | c.1058+206G>T | Intron (SNP) | VAF 24/127 reads (19%) | called by muse, mutect2, varscan2
- SNORD115-3 | n.80C>A | RNA (SNP) | VAF 18/298 reads (6%) | called by muse, mutect2
- SPATA31C2 | n.1092C>A | RNA (SNP) | VAF 21/241 reads (9%) | called by muse, mutect2
- SQSTM1 | c.969+50C>T | Intron (SNP) | VAF 12/144 reads (8%) | catalogued as rs1454862586; called by muse, mutect2
- TPRXL | n.779C>A | RNA (SNP) | VAF 27/293 reads (9%) | catalogued as rs1378637369; called by muse, mutect2
- TPRXL | n.781C>A | RNA (SNP) | VAF 28/308 reads (9%) | called by muse, mutect2
- XPO6 | c.3276+30G>C | Intron (SNP) | VAF 30/378 reads (8%) | called by muse, mutect2
- XXYLT1 | c.652+19266G>T | Intron (SNP) | VAF 12/106 reads (11%) | called by muse, mutect2, varscan2
